Somatic mutation profile of tumor specimen TARGET-40-PAPIJR-01A (aliquot TARGET-40-PAPIJR-01A-01D) from TARGET case TARGET-40-PAPIJR, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.6 years (4,597 days).
Specimen TARGET-40-PAPIJR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4169a00-b2b1-4259-9a84-946311db74e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAPIJR-10A (Blood Derived Normal), aliquot TARGET-40-PAPIJR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb40eabb-8ede-49a1-af1c-538fd1be96f9

The open-access MAF lists 35 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Intron 6, 5'UTR 3, Nonsense Mutation 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B3 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1557010446, CM156865, COSV54839891; called by muse, mutect2, varscan2
- CHRNA9 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59573635; called by muse, mutect2, varscan2
- HRNR | c.964C>A p.H322N | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.049); catalogued as COSV64263074; called by muse, mutect2
- KCNA2 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104412955, COSV60369172; called by muse, mutect2, varscan2
- MET | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs949765512; called by muse, mutect2, varscan2
- PHF12 | c.2679C>G p.I893M | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV60455921; called by muse, mutect2, varscan2
- SEMA3F | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as rs766517998, COSV50038506; called by muse, mutect2, varscan2
- TRPV5 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.243); catalogued as rs760942343; called by muse, mutect2, varscan2
- ASPHD2 | c.224G>A p.C75Y | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CANT1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNA5 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRACDL | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, varscan2
- DHX36 | c.1524G>C p.L508F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MET | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MET | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- RASAL2 | c.128C>G p.A43G | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SLC16A2 | c.939G>C p.M313I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIM23 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2
- CYLC1 | c.1407G>A p.K469= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV61414182; called by muse, mutect2
- EP400 | c.5493G>A p.E1831= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs770218371; called by muse, mutect2, varscan2
- FUS | c.159C>T p.S53= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- LGALS9B | c.852C>T p.I284= (on ENST00000423676 / NM_001367292.1; = p.I283= on NM_001042685.2) | Silent (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- OR4A15 | c.162T>A p.G54= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- SHMT1 | c.249T>C p.Y83= | Silent (SNP) | VAF 30/219 reads (14%) | catalogued as COSV57398394; called by muse, mutect2, varscan2
- ASMTL | c.225+38C>A | Intron (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- DHRS2 | c.421-147G>A | Intron (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- DNAH3 | c.2366+113G>A | Intron (SNP) | VAF 22/52 reads (42%) | called by mutect2, varscan2
- LGALS9B | c.673-101C>T | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- LGALS9B | c.577-112C>T | Intron (SNP) | VAF 23/100 reads (23%) | called by muse, varscan2
- MYCN | c.-25C>T | 5'UTR (SNP) | VAF 5/20 reads (25%) | catalogued as rs763298242; called by muse, mutect2, varscan2
- RNU6-467P | chr17:20321277 C>T | 5'Flank (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- SGSH | c.950-66G>A | Intron (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2
- TBC1D27P | n.3708C>T | RNA (SNP) | VAF 29/156 reads (19%) | catalogued as rs537024984; called by muse, mutect2, varscan2
- ZNF580 | c.-4C>T | 5'UTR (SNP) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- ZNF580 | c.-3C>T | 5'UTR (SNP) | VAF 6/20 reads (30%) | called by mutect2, varscan2
